Somatic mutation profile of tumor specimen 0DI1ZI from CCDI case PBBUYC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 16.2 years (5,922 days).
Specimen 0DI1ZI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04e98203-61ab-44f3-9462-0adcc3de2de8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI1JQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de070f68-1287-4991-888a-0f0fcbbc2f1d

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 188/930 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MCM3AP | c.4120C>T p.P1374S | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs950604254; called by mutect2, varscan2
- NDUFA9 | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 143/756 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs61754988; called by muse, mutect2, varscan2
- NEIL3 | c.739A>G p.K247E | Missense Mutation (SNP) | VAF 48/832 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1217971518; called by muse, mutect2
- TDRD15 | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 69/1061 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1243170204; called by muse, mutect2
- C3orf85 | c.183+145del | Intron (DEL) | VAF 4/33 reads (12%) | called by mutect2, varscan2
- ESYT3 | c.915+71G>A | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs899644332; called by mutect2, varscan2
